Somatic mutation profile of tumor specimen C3L-00908-01 (aliquot CPT0086350006) from CPTAC case C3L-00908, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 60.7 years (22,179 days).
Specimen C3L-00908-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1dfeb984-4b62-4dcc-b326-70a370763c0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00908-31 (Blood Derived Normal), aliquot CPT0087380001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/675a8261-26f1-4ca6-806a-386c0a97ce94

The open-access MAF lists 66 somatic variants for this specimen: 49 protein-altering or splice-affecting, 8 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 8, Intron 7, Frame Shift Del 2, Nonsense Mutation 2, In Frame Del 2, Splice Site 1, Splice Region 1, RNA 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 67/328 reads (20%) | catalogued as rs5030813, CM961428, COSV56543950, COSV56550839; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACP3 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 57/238 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.576); catalogued as COSV100313282; called by muse, mutect2, varscan2
- BAP1 | c.554G>A p.G185E | Missense Mutation (SNP) | VAF 77/399 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553645794, COSV99963208; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNNB1 | c.1915C>T p.P639S | Missense Mutation (SNP) | VAF 91/409 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.296); catalogued as rs1304150324; called by muse, mutect2, varscan2
- DHX16 | c.2224G>A p.A742T | Missense Mutation (SNP) | VAF 50/263 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.235); catalogued as COSV53312842; called by muse, mutect2, varscan2
- EPHB2 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1459453657; called by muse, mutect2, varscan2
- GOLM2 | c.311G>C p.R104T | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs763287981; called by muse, varscan2
- LRRC8A | c.211G>A p.G71S | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as rs144778925; called by muse, mutect2, varscan2
- OR2A2 | c.796C>T p.R266* | Nonsense Mutation (SNP) | VAF 66/308 reads (21%) | catalogued as rs536132673, COSV68872204; called by muse, mutect2, varscan2
- PNPLA6 | c.3359T>C p.L1120P (on ENST00000414982 / NM_001166111.2; = p.L1072P on NM_006702.5) | Missense Mutation (SNP) | VAF 115/605 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55373482; called by muse, mutect2, varscan2
- RIMS1 | c.2993G>A p.R998Q | Missense Mutation (SNP) | VAF 46/255 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.099); catalogued as rs1414432029, COSV53450436; called by muse, mutect2, varscan2
- SEC16A | c.6758G>A p.G2253D | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as rs896059806; called by muse, mutect2
- SETBP1 | c.3669G>C p.K1223N | Missense Mutation (SNP) | VAF 97/563 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs1172547169; called by muse, mutect2, varscan2
- SF3B1 | c.2318T>G p.L773R | Missense Mutation (SNP) | VAF 43/218 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59223584; called by muse, mutect2, varscan2
- SLC7A1 | c.281C>T p.T94M | Missense Mutation (SNP) | VAF 44/271 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs756760070, COSV66330180; called by muse, mutect2, varscan2
- STIM1 | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 54/315 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.268); catalogued as rs1338973695, COSV56157113; called by muse, mutect2, varscan2
- ABAT | c.1472T>A p.I491N | Missense Mutation (SNP) | VAF 83/501 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ABCG5 | c.634A>C p.K212Q | Missense Mutation (SNP) | VAF 61/414 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- ADAMTS12 | c.634+5T>G | Splice Region (SNP) | VAF 48/273 reads (18%) | called by muse, mutect2, varscan2
- AKIRIN2 | c.226C>A p.L76I | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ATIC | c.388A>C p.T130P | Missense Mutation (SNP) | VAF 60/371 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- BCR | c.3536T>A p.F1179Y | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- COPG1 | c.939+1G>C p.X313_splice | Splice Site (SNP) | VAF 13/107 reads (12%) | called by muse, mutect2, varscan2
- CROCC2 | c.3715del p.L1239Sfs*156 | Frame Shift Del (DEL) | VAF 15/105 reads (14%) | called by mutect2, pindel, varscan2
- CYRIB | c.755T>G p.F252C | Missense Mutation (SNP) | VAF 42/191 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GOLIM4 | c.1664A>G p.N555S | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HDAC10 | c.173A>T p.E58V | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- HELZ2 | c.2519G>A p.S840N (on ENST00000467148 / NM_001037335.2; = p.S271N on NM_033405.3) | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, varscan2
- HINT3 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 37/227 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- ITIH4 | c.1200T>A p.N400K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- MCTP2 | c.78G>T p.K26N | Missense Mutation (SNP) | VAF 60/252 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- MYO5A | c.755A>T p.Q252L | Missense Mutation (SNP) | VAF 54/340 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- MYO9B | c.952T>C p.Y318H | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- NUTM2G | c.518G>T p.G173V | Missense Mutation (SNP) | VAF 30/654 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.268); called by muse, mutect2
- PCDHB11 | c.1261A>G p.I421V | Missense Mutation (SNP) | VAF 60/382 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- PDZRN4 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated, low confidence (0.43); called by muse, mutect2
- PHF8 | c.2386A>G p.S796G (on ENST00000357988 / NM_001184896.1; = p.S760G on NM_015107.3) | Missense Mutation (SNP) | VAF 38/261 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.107); called by muse, varscan2
- PLCH1 | c.1043G>T p.W348L (on ENST00000340059 / NM_001130960.2; = p.W360L on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLCL2 | c.2745del p.V916Wfs*18 (on ENST00000615277 / NM_001144382.2; = p.V790Wfs*18 on NM_015184.5) | Frame Shift Del (DEL) | VAF 26/145 reads (18%) | called by mutect2, pindel, varscan2
- PRDM16 | c.3067C>A p.L1023M | Missense Mutation (SNP) | VAF 43/198 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- SLC27A4 | c.433G>A p.G145S | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SORCS1 | c.2709_2711del p.K903del | In Frame Del (DEL) | VAF 23/141 reads (16%) | called by mutect2, pindel, varscan2
- SPATS2 | c.382G>A p.G128S | Missense Mutation (SNP) | VAF 42/262 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- SPECC1L | c.812dup p.L271Ffs*16 | Frame Shift Ins (INS) | VAF 103/614 reads (17%) | called by mutect2, pindel, varscan2
- ST7 | c.251_263delinsG p.Y84_Y88delinsC | In Frame Del (DEL) | VAF 44/201 reads (22%) | called by pindel, varscan2*
- SUN3 | c.386A>C p.Q129P | Missense Mutation (SNP) | VAF 41/190 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- TCN1 | c.425C>G p.T142S | Missense Mutation (SNP) | VAF 82/412 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM68 | c.952G>A p.A318T (on ENST00000434581 / NM_001363177.1; = p.A251T on NM_152417.3) | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UBN1 | c.3136A>G p.I1046V | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DNAH5 | c.12963C>T p.D4321= | Silent (SNP) | VAF 95/520 reads (18%) | catalogued as rs768902025; called by muse, mutect2, varscan2
- HRNR | c.1476A>G p.G492= | Silent (SNP) | VAF 97/478 reads (20%) | catalogued as rs764408426; called by muse, mutect2, varscan2
- KAT6A | c.5772C>T p.S1924= | Silent (SNP) | VAF 31/142 reads (22%) | catalogued as COSV55907098; called by muse, mutect2, varscan2
- LPIN3 | c.1695C>T p.D565= | Silent (SNP) | VAF 41/191 reads (21%) | catalogued as rs1352186685; called by muse, mutect2, varscan2
- PTPRC | c.36T>C p.F12= | Silent (SNP) | VAF 148/500 reads (30%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.2406C>T p.N802= | Silent (SNP) | VAF 57/330 reads (17%) | catalogued as COSV55913623; called by muse, mutect2, varscan2
- SMPDL3A | c.789C>T p.N263= | Silent (SNP) | VAF 51/308 reads (17%) | called by muse, mutect2, varscan2
- SQSTM1 | c.729T>C p.S243= | Silent (SNP) | VAF 73/553 reads (13%) | called by muse, mutect2, varscan2
- AC092329.3 | c.-211-589G>C | Intron (SNP) | VAF 23/274 reads (8%) | called by muse, mutect2
- FRMPD4 | c.-36C>T | 5'UTR (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- NPIPP1 | n.845A>T | RNA (SNP) | VAF 119/768 reads (15%) | called by muse, varscan2
- OR9Q1 | c.-15+53346A>T | Intron (SNP) | VAF 71/380 reads (19%) | called by muse, mutect2, varscan2
- PLEKHS1 | c.929+30C>A | Intron (SNP) | VAF 34/185 reads (18%) | called by muse, mutect2, varscan2
- PSMA4 | c.-23-25dup | Intron (INS) | VAF 20/145 reads (14%) | called by mutect2, pindel, varscan2
- RBM22 | c.55-71C>A | Intron (SNP) | VAF 27/152 reads (18%) | called by muse, mutect2, varscan2
- SLC2A11 | c.21+33C>G | Intron (SNP) | VAF 23/138 reads (17%) | called by muse, mutect2
- TNK2 | c.-18-6823G>A | Intron (SNP) | VAF 16/54 reads (30%) | catalogued as rs1299637683; called by muse, mutect2, varscan2
